Somatic mutation profile of tumor specimen BA2206D (aliquot aq-BA2206D) from BEATAML1.0 case 2225, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.8 years (17,109 days).
Specimen BA2206D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84d35820-f196-4f76-a6c6-c3fdc53a9442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2988D (Solid Tissue Normal), aliquot aq-BA2988D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26d54094-364e-49ea-81f5-50ef980e79f7

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 35/64 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6772C>T p.R2258* (on ENST00000358273 / NM_001042492.3; = p.R2237* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 67/265 reads (25%) | catalogued as rs876658541, CM000815, COSV62192184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- NCAM2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs766008654, COSV53070568, COSV53071940; called by muse, varscan2
- PCDHB4 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs782065445; called by muse, mutect2, varscan2
- SOS1 | c.806T>A p.M269K | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as CM070275, CM074570, COSV67674247, COSV67676625; called by muse, mutect2, varscan2
- USO1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772397784, COSV53705126; called by muse, mutect2, varscan2
- ATRX | c.4661_4662dup p.N1555Efs*7 | Frame Shift Ins (INS) | VAF 27/122 reads (22%) | called by mutect2, pindel, varscan2
- CD82 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.422); called by muse, mutect2
- GRIN3B | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.081); called by muse, mutect2
- MYO10 | c.1393C>G p.H465D | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NDST4 | c.1866C>A p.S622R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCNX1 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- SH3PXD2B | c.2233G>T p.V745F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.08); called by muse, mutect2
- TRIM41 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ITGB5 | c.2277C>T p.S759= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs199862649; called by muse, mutect2, varscan2
- MYH6 | c.5751C>T p.S1917= | Silent (SNP) | VAF 11/290 reads (4%) | catalogued as COSV59306287; called by muse, mutect2
- MYO16 | c.46C>A p.R16= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- MYO1C | c.441C>T p.T147= (on ENST00000648651 / NM_001080779.2; = p.T112= on NM_033375.5) | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs751201105; called by muse, mutect2, varscan2
- PLXNC1 | c.297C>A p.P99= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- RAB11FIP5 | c.1605G>T p.V535= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- RYR2 | c.13080C>T p.S4360= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs369964660, COSV100772573; ClinVar: likely benign; called by mutect2, varscan2
- POLD2 | chr7:44123520 C>T | 5'Flank (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
